Somatic mutation profile of tumor specimen TCGA-A3-3376-01A (aliquot TCGA-A3-3376-01A-02D-1421-08) from TCGA case TCGA-A3-3376, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.9 years (18,954 days).
Specimen TCGA-A3-3376-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e76f7db8-3777-4fab-a15b-e97e39c78bf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3376-11A (Solid Tissue Normal), aliquot TCGA-A3-3376-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a973bc-c601-4dbf-94df-94d8b5ef68e4

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Frame Shift Del 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GAT1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as COSV60820961; called by muse, mutect2
- C14orf39 | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.294); catalogued as COSV58785810; called by muse, mutect2
- CCDC3 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.468); catalogued as COSV66562203; called by muse, mutect2, varscan2
- CCT8L2 | c.264G>C p.W88C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63464146; called by muse, mutect2, varscan2
- CDC16 | c.300T>G p.N100K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV52962608; called by muse, mutect2, varscan2
- CYLD | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV61097952; called by muse, mutect2, varscan2
- DENND4A | c.3602G>C p.R1201T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.105); catalogued as COSV71267297; called by muse, mutect2
- DOP1A | c.761T>C p.F254S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52720077; called by muse, mutect2, varscan2
- DYRK1A | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV58297719; called by muse, mutect2, varscan2
- DYRK1A | c.836C>G p.P279R | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV58297727; called by muse, mutect2, varscan2
- KLF10 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53437084; called by muse, mutect2, varscan2
- KMT2C | c.9181C>A p.Q3061K | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51516492, COSV51520902; called by muse, varscan2
- KMT2E | c.3595T>C p.C1199R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV57581315; called by muse, mutect2, varscan2
- LMTK2 | c.3050C>G p.T1017S | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52006021; called by muse, mutect2, varscan2
- LSM1 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54862905; called by muse, mutect2
- MFSD14A | c.1201A>C p.K401Q | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV54930935; called by muse, mutect2, varscan2
- NEGR1 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV60829760, COSV60880008; called by muse, mutect2, varscan2
- NUP85 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 90/533 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as COSV55467467; called by muse, mutect2, varscan2
- PIK3R1 | c.1541G>T p.R514L (on ENST00000521381 / NM_181523.3; = p.R244L on NM_181504.4) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV57142438; called by muse, mutect2, varscan2
- PPP2R5B | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51214316; called by muse, mutect2, varscan2
- PRRC2A | c.1372T>C p.S458P | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV63225131; called by muse, mutect2, varscan2
- PTPRJ | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV69255181; called by muse, mutect2, varscan2
- QRSL1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV64688240; called by muse, mutect2, varscan2
- RAPGEF4 | c.1724G>A p.R575K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.456); catalogued as COSV51419011; called by muse, mutect2, varscan2
- SDHB | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.399); catalogued as COSV64965903; called by muse, mutect2, varscan2
- SEMG2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65648084; called by muse, mutect2, varscan2
- SLC6A5 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54233627; called by muse, mutect2, varscan2
- SOAT2 | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV56861856; called by muse, mutect2, varscan2
- SOAT2 | c.875T>G p.V292G | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV56861876; called by muse, mutect2, varscan2
- SPEN | c.4369T>G p.S1457A | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV65368579; called by muse, mutect2
- STOML3 | c.316del p.L106Sfs*6 | Frame Shift Del (DEL) | VAF 27/214 reads (13%) | catalogued as COSV65510086; called by mutect2, pindel, varscan2
- TMEM94 | c.1696T>A p.S566T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58601036; called by muse, mutect2, varscan2
- UBR1 | c.2574C>G p.N858K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51938048; called by mutect2, varscan2
- ZNF510 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.135); catalogued as COSV56299457; called by muse, mutect2, varscan2
- ANGPTL1 | c.1342del p.S448Lfs*3 | Frame Shift Del (DEL) | VAF 24/211 reads (11%) | called by mutect2, varscan2
- SLC45A3 | c.1304del p.P435Lfs*107 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- TATDN3 | c.564del p.F189Sfs*8 | Frame Shift Del (DEL) | VAF 21/137 reads (15%) | called by mutect2, pindel, varscan2
- ANKIB1 | c.2919C>A p.I973= | Silent (SNP) | VAF 46/277 reads (17%) | catalogued as COSV56067060, COSV99729908; called by muse, mutect2, varscan2
- C14orf39 | c.1074G>A p.Q358= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV58785789; called by muse, mutect2
- C1orf162 | c.60A>C p.T20= | Silent (SNP) | VAF 47/277 reads (17%) | catalogued as COSV59059811; called by muse, mutect2, varscan2
- C1orf189 | c.57T>C p.L19= | Silent (SNP) | VAF 9/192 reads (5%) | catalogued as COSV62967049; called by muse, mutect2
- CIAO2B | c.438G>A p.L146= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV57698090; called by muse, mutect2, varscan2
- DOCK8 | c.3450T>A p.T1150= | Silent (SNP) | VAF 24/195 reads (12%) | catalogued as COSV66624654; called by muse, mutect2, varscan2
- EPHA7 | c.1815C>G p.T605= | Silent (SNP) | VAF 33/276 reads (12%) | catalogued as COSV100993321, COSV65193880; called by muse, mutect2, varscan2
- P3H2 | c.1725C>A p.L575= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV60029337; called by muse, mutect2, varscan2
- SORCS1 | c.3093T>C p.T1031= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV53913794; called by muse, mutect2, varscan2
- SPIB | c.291C>A p.A97= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as COSV54533085; called by muse, mutect2, varscan2
- TEX13A | c.426G>A p.E142= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV61189107; called by muse, mutect2, varscan2
- YTHDC2 | c.885A>G p.V295= | Silent (SNP) | VAF 30/504 reads (6%) | catalogued as COSV50757656; called by muse, mutect2
- RPS3A | c.564-300C>T | Intron (SNP) | VAF 11/88 reads (13%) | catalogued as rs191265801, COSV56839956; called by muse, mutect2, varscan2
